Somatic mutation profile of tumor specimen TCGA-VS-A9V0-01A (aliquot TCGA-VS-A9V0-01A-11D-A42O-09) from TCGA case TCGA-VS-A9V0, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 58.1 years (21,215 days).
Specimen TCGA-VS-A9V0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 424758eb-fbd8-4ce6-b44b-b44e4a2f3fb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9V0-10A (Blood Derived Normal), aliquot TCGA-VS-A9V0-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c9c4897-2c74-49c0-85c5-227a5383ae7c

The open-access MAF lists 57 somatic variants for this specimen: 42 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 38, Silent 15, Frame Shift Del 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1514G>T p.R505L (on ENST00000281708 / NM_001349798.2; = p.R425L on NM_018315.5) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2B1 | c.712A>C p.I238L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as COSV53809557; called by muse, mutect2
- BAZ1A | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1227972815, COSV100701128; called by muse, mutect2, varscan2
- BOD1L1 | c.2620G>A p.D874N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99239096; called by muse, mutect2, varscan2
- BRINP3 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV66513604, COSV66513646; called by muse, mutect2, varscan2
- C21orf58 | c.158C>G p.A53G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV99387998; called by muse, mutect2, varscan2
- CHST13 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100081108; called by muse, mutect2, varscan2
- CNTNAP5 | c.3320G>A p.R1107Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs1461542843, COSV70474928; called by muse, mutect2, varscan2
- CSF1R | c.2368C>T p.H790Y | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV53846774; called by muse, mutect2, varscan2
- DUSP6 | c.762del p.K254Nfs*26 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | catalogued as COSV54379298; called by mutect2, pindel, varscan2
- EEF1A2 | c.327G>A p.A109= | Splice Region (SNP) | VAF 7/18 reads (39%) | catalogued as COSV53208966; called by muse, mutect2, varscan2
- EP300 | c.4309G>A p.A1437T | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99608228; called by muse, mutect2, varscan2
- FAM3B | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100415885; called by muse, mutect2, varscan2
- FHL1 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100600753, COSV61781589; called by muse, mutect2, varscan2
- FLOT1 | c.1138C>A p.L380M | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100013328; called by muse, mutect2
- GPR143 | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101102199; called by muse, mutect2, varscan2
- GUCY1A1 | c.1138T>G p.L380V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56655671, COSV99637581; called by muse, mutect2, varscan2
- HDX | c.1952T>A p.L651Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99947101; called by muse, mutect2, varscan2
- INPP4A | c.1154C>A p.T385N | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as COSV99303358; called by muse, mutect2, varscan2
- INSIG1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100452954; called by muse, mutect2, varscan2
- KDM2A | c.1882C>G p.Q628E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.103); catalogued as rs1217106563, COSV100445514; called by muse, mutect2, varscan2
- LRRC7 | c.2858G>A p.R953H (on ENST00000651989 / NM_001370785.2; = p.R920H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.019); catalogued as rs141932871; called by muse, mutect2, varscan2
- MAGEE1 | c.295G>C p.G99R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100819369; called by muse, mutect2, varscan2
- MKRN3 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100091042; called by muse, mutect2, varscan2
- NRAP | c.1821G>C p.Q607H (on ENST00000359988 / NM_001322945.2; = p.Q572H on NM_006175.4) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.88); catalogued as COSV100748392; called by muse, mutect2, varscan2
- NRXN1 | c.2723C>G p.T908S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV100454522; called by muse, mutect2, varscan2
- NUP155 | c.3778C>T p.R1260C (on ENST00000231498 / NM_153485.3; = p.R1201C on NM_004298.4) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs764447032, COSV99192648; called by muse, mutect2, varscan2
- OR52M1 | c.159A>G p.I53M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100798579; called by muse, mutect2, varscan2
- PGAM4 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as COSV100430634; called by muse, mutect2, varscan2
- PLCL2 | c.454G>T p.V152F (on ENST00000615277 / NM_001144382.2; = p.V26F on NM_015184.5) | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs141837634, COSV101196677; called by muse, mutect2, varscan2
- PTPN9 | c.1229G>T p.R410I | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV60725997; called by muse, mutect2, varscan2
- RAB39B | c.308G>T p.W103L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101034958; called by muse, mutect2, varscan2
- RAPGEF4 | c.2860A>G p.I954V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV99910380; called by muse, mutect2, varscan2
- SLIT2 | c.2825G>A p.R942Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as rs752129779, COSV56575249; called by muse, mutect2, varscan2
- SPON1 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated (0.23); PolyPhen benign (0.222); catalogued as rs782247472, COSV59965154; called by muse, mutect2, varscan2
- TAPT1 | c.1307A>G p.Y436C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58822856; called by muse, mutect2, varscan2
- TSPYL5 | c.848A>G p.E283G | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100438970; called by muse, mutect2, varscan2
- UTRN | c.8964G>T p.Q2988H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV100837831, COSV62304418; called by muse, mutect2, varscan2
- HHIP | c.767del p.P256Lfs*21 | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- MED12 | c.4901A>G p.K1634R | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.117); called by muse, mutect2
- SLC27A5 | c.245del p.P82Qfs*10 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | called by mutect2, varscan2
- CCDC93 | c.723G>A p.E241= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs188217202, COSV100098643; called by muse, mutect2, varscan2
- FAT1 | c.12495T>A p.A4165= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV101499291; called by muse, mutect2, varscan2
- MAFK | c.21G>A p.P7= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs778710471, COSV99868104; called by muse, mutect2, varscan2
- MTF1 | c.1788G>A p.E596= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100888622; called by mutect2, varscan2
- MYO18B | c.7578T>C p.S2526= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV59129026; called by muse, mutect2, varscan2
- NCAPH | c.201G>A p.R67= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV53637198, COSV99545749; called by muse, mutect2, varscan2
- PCDHA7 | c.1233C>T p.S411= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV100971410; called by muse, mutect2
- PRR5-ARHGAP8 | c.1332C>A p.S444= (on ENST00000352766; = p.S365= on NM_181334.5) | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as COSV100424148, COSV61235340; called by muse, mutect2, varscan2
- RBPJ | c.117T>C p.Y39= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as rs746787764, COSV100623580; called by muse, mutect2, varscan2
- SLC29A1 | c.249C>G p.V83= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100505731; called by muse, mutect2, varscan2
- SPEG | c.3936C>T p.A1312= | Silent (SNP) | VAF 44/68 reads (65%) | catalogued as COSV100404159, COSV56673061; called by muse, mutect2, varscan2
- TBC1D25 | c.1617C>T p.L539= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV100952135; called by muse, mutect2, varscan2
- TRIOBP | c.5445A>C p.T1815= (on ENST00000644935 / NM_001039141.3; = p.T102= on NM_007032.5) | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100462281; called by muse, mutect2, varscan2
- TUBB6 | c.471G>A p.E157= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as rs758140585, COSV99301783; called by muse, mutect2, varscan2
- UTP25 | c.1335G>A p.S445= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as rs1334874786, COSV71966245; called by muse, mutect2, varscan2
